Somatic mutation profile of tumor specimen MP2PRT-PATJIK-TMP1-A (aliquot MP2PRT-PATJIK-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATJIK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,340 days).
Specimen MP2PRT-PATJIK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16c0ba13-3559-453e-8ba5-37f3d3b91494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJIK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJIK-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70f06276-d648-4c1b-9ab9-409d752368f9

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, RNA 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 50/182 reads (27%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 30/271 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 170/633 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119787, COSV63328842; called by muse, varscan2
- PTPN5 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.469); catalogued as rs200135035, COSV100660004; called by muse, mutect2, varscan2
- UNC5A | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1228167410; called by muse, mutect2, varscan2
- ZFP92 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 150/885 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs782738099; called by muse, mutect2, varscan2
- CBL | c.1100_1107delinsGTCCCAAG p.Q367_E369delinsRPK | Missense Mutation (ONP) | VAF 33/128 reads (26%) | called by pindel, varscan2*
- SWAP70 | c.1585_1586insGC p.N529Sfs*17 | Frame Shift Ins (INS) | VAF 34/148 reads (23%) | called by mutect2, pindel*, varscan2
- USP9X | c.5966_5967del p.R1989Kfs*12 | Frame Shift Del (DEL) | VAF 243/558 reads (44%) | called by pindel, varscan2
- ARMCX1 | c.1353C>G p.T451= | Silent (SNP) | VAF 71/223 reads (32%) | called by muse, mutect2, varscan2
- CD7 | c.696G>A p.T232= | Silent (SNP) | VAF 72/231 reads (31%) | catalogued as rs772804521; called by muse, mutect2, varscan2
- GRIA2 | c.1710C>T p.Y570= | Silent (SNP) | VAF 113/240 reads (47%) | catalogued as rs538981621, COSV52380934, COSV99642409; called by muse, mutect2, varscan2
- NMRAL2P | n.193C>T | RNA (SNP) | VAF 49/398 reads (12%) | called by muse, mutect2, varscan2
